Surgical pathology report (de-identified scan), TCGA case TCGA-78-7158, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7158-01A (Primary Tumor).

[page 1 of 2]
SEE SUPPLEMENTARY REPORT BELOW

HISTORY

LLL adenocarcinoma.

MACROSCOPIC

Four specimens received:

1: The first specimen is labelled 'left lower lobe' and consists of a left lower lobe of lung measuring 160 (SI) x 100 (AP) x 90 mm (ML). The pleural surface is puckered on the anteromedial aspect of the superior portion of the lobe and underlying this there is a firm mass. This has been incised prior to reception in the laboratory. Otherwise the pleural surface is unremarkable. There are two suture lines extending from the hilum. One extends superiorly and measures 40 mm the other inferiorly and measures 35 mm. Sectioning reveals a large poorly circumscribed tumour mass underlying the area of pleural puckering described. Defining its dimensions macroscopically is difficult but it would be approximately 70 (SI) x 60 (AP) x 70 mm (ML). It is made difficult as the tumour merges imperceptibly with probable endogenous lipoid pneumonia in the surrounding parenchyma. The tumour mass extends from the anterior pleural surface to the posterior pleural surface and extends to within 10 mm of the bronchial resection margin. A discrete firm nodule is noted in the mid lateral portion of the lobe which measures 5 x 5 x 5 mm. This appears to be separate from the main tumour. [1A, bronchial resection margin; 1B-1C peribronchial lymph nodes; 1D-1F tumour and relationship to anterior pleural surface; 1G, probable tumour and superior aspect of lobe; 1H, tumour and posterior aspect of lobe; 1I, inferior aspect of tumour; 1J, section including the firm small nodule described; 1K, section of normal lung.] Specimen has been sampled for research.

2: The second specimen is labelled 'pulmonary vein' and consists of what appears to be a piece of lymphoid tissue measuring 14 x 8 x 7 mm. Sectioning reveals only lymph node. [Bisected, BIT, 2A.]

3: The third specimen is labelled 'No. 9 lymph node' and consists of a piece of nodal tissue measuring 33 x 15 x 17 mm. [Trisected, BIT, 3A-3B.]

4: The fourth specimen is labelled 'No. 10 lymph node' and consists of a single piece of nodal tissue measuring 24 x 14 x 14 mm. [Bisected, BIT, 4A.]

MICROSCOPIC

1. Sections show a moderately differentiated adenocarcinoma. The tumour has a papillary architecture and includes areas with psammoma bodies and 'Orphan Annie' nuclei. There is a small component with features of micropapillary differentiation. Although this may represent a lung primary, special stains are being performed to exclude a thyroid or an ovarian primary. Surrounding the mass, there is a patchy lepidic growth pattern and carcinoma is identified both within the airspaces and lymphatics in the section from the normal lung. The nodule in the mid lateral portion of the lobe is a focus of tumour with a surrounding lepidic growth pattern. The lesion is subpleural and the tumour invades into the visceral pleural surface. There is possible focal surface involvement. Blood vessel and lymphatic invasion is present. No perineural permeation is seen. Adenocarcinoma is present within all the peribronchial lymph nodes including one at the bronchial resection margin. Extracapsular extension is noted. Also present at the bronchial resection margin, there is lymphatic permeation within the mucosa. No dysplasia is seen. There is insufficient normal lung parenchyma for assessment of abnormalities.

2. Sections show a lymph node involved by metastatic adenocarcinoma.

3. Sections show lymph nodes involved by metastatic adenocarcinoma.

4. Sections show lymph nodes involved by metastatic adenocarcinoma.

SUMMARY

Left lower lobe and pulmonary vein, No. 9 and No. 10 lymph nodes:

A: Moderately differentiated papillary adenocarcinoma; special stains being performed; at least 70 mm in maximal dimension with extensive involvement of the surrounding lung including the section of

[page 2 of 2]
"normal" lung.

B: Blood vessel and lymphatic invasion present but no perineural permeation is seen.

C: Visceral pleural invasion identified; bronchial margin involved (mucosal lymphatic permeation).

D: Lymph node metastases within all sampled nodes.

E: T4N2MX

F: Non-neoplastic lung; Involved by carcinoma

SUPPLEMENTARY REPORT

The tumour cells are stains strongly for TTF 1 but are negative for thyroglobulin. Some patchy positivity is identified with progesterone receptor markers but no convincing positivity is seen with the oestrogen receptor markers. This immunohistochemical profile would support a diagnosis of primary pulmonary adenocarcinoma.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file 9f259aa2-9721-4cfe-95ef-ff1190e7c069 (TCGA-78-7158.1AC638BD-3DA2-472D-90BF-1E100BFCDB19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).